Somatic mutation profile of tumor specimen TARGET-20-PATFCZ-09A (aliquot TARGET-20-PATFCZ-09A-01D) from TARGET case TARGET-20-PATFCZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.8 years (6,126 days).
Specimen TARGET-20-PATFCZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92a5e426-bf40-4d08-a64b-1fa75bfa8754.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATFCZ-14A (Bone Marrow Normal), aliquot TARGET-20-PATFCZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb8e6a8d-ded6-485e-adff-92825a199d6c

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867564832, COSV50631687, COSV50635445; called by muse, mutect2, varscan2
- MYH4 | c.3647G>A p.R1216Q | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs766999823, COSV99700374, COSV99701442; called by muse, mutect2, varscan2
- RUNX1 | c.404G>C p.R135T (on ENST00000344691 / NM_001001890.3; = p.R162T on NM_001754.5) | Missense Mutation (SNP) | VAF 154/182 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55868310; called by muse, mutect2, varscan2
- NLRP3 | c.627C>T p.P209= | Silent (SNP) | VAF 132/299 reads (44%) | catalogued as rs554444159, COSV60227943; ClinVar: likely benign; called by muse, mutect2, varscan2
